Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JV, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JV-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: M
ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: SPGD

1. "Spleen." Received in a large container is a 420 gm, 14 x 12 x 6 cm spleen, semi-firm and red on cut surfaces. Representative sections.
2. "Omentum." Received in a large container is a 56 x 10 x 2 cm, fibroadipose and separate 13 x 6 x 2 cm. No mass or lesion. Representative sections
3. "Perirenal lymph node." Received is a 1 cm, pink-yellow lymph node. Bisected.
4. "Retroperitoneal fat." Received in a small container are portions of fibroadipose aggregating to 6 x 5 x 3 cm. No mass or lesion. Representative sections.
5. "Left adrenal and left kidney." Received in a large container, a 1525 gram kidney and adrenal. A 17 x 11 x 12 cm adrenal mass attached to a 13 x 4 x 5 cm kidney with attached adipose. The adrenal mass is completely encased by a pseudocapsule and membranous/fascial layer. Attached to the kidney is 2.5 cm segment of ureter. Inferior pole of kidney contains a 3.6 x 3.5 x 1.5 cm simple cyst bulging from the cortex. A 2 cm dilated vessel partially adherent to inferior adrenal contains a branch entering inferior renal hilum. While the adrenal is adherent to the renal capsule and sharing vessels, the kidney is not involved by tumor. After trimming kidney and adipose, the adrenal mass weighs 1125 grams. No grossly identifiable residual adrenal. The majority of the adrenal mass is soft and semi-solid with the central third yellow, grumous and necrotic while the peripheral is nodular, pink-tan and soft with foci of necrosis and hemorrhage. The mass abuts the fascia (less than 0.1 cm).
- 5A. Kidney.
- 5B. Sewn vessels in ureter.
- 5C.-L. Representative adrenal including capsule and where fat adherent. Note: Portion sent to tissue procurement.

PROCEDURE: SPDX

1. Spleen, resection: No significant abnormality.
2. Omentum, resection: No significant abnormality.
3. Lymph node, perirenal, excision: One lymph node negative for neoplasm (0/1).
4. Retroperitoneal fat, excision: Negative for neoplasm.
5. Left kidney and adrenal gland, resection: Adrenocortical carcinoma (17 cm). No vascular invasion. Margins free of tumor. Unremarkable kidney.

ICD-8-3
Carcinoma, adrenal cortical 8376/3
Site: Adrenal Gland, Cortex C74.0
QID 1/30/13

Case is (for Tel.)		

Source: NCI Genomic Data Commons file f003e3f1-5e83-44ca-b180-c04042505084 (TCGA-OR-A5JV.35A41AE5-44E3-45D1-A2C0-523496732A75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).